Somatic mutation profile of tumor specimen 12110cb8-8da4-4461-ac1a-1af490 (aliquot 12110cb8-8da4-4461-ac1a-1af490_D6_1) from CPTAC case 22BR005, project CPTAC-2 (Breast — Ductal and Lobular Neoplasms). Sex at birth: female; Primary diagnosis: Infiltrating duct and lobular carcinoma; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIB; Age at diagnosis: 45.9 years (16,759 days).
Specimen 12110cb8-8da4-4461-ac1a-1af490: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c7f7f6a5-7aea-4e80-86f1-d77c27e579c5.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 7604cab5-d108-4fbd-8bc7-2bee52 (Blood Derived Normal), aliquot 7604cab5-d108-4fbd-8bc7-2bee52_D1_1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ea101fcb-6295-43cf-9dc3-dbe96262f776

The open-access MAF lists 125 somatic variants for this specimen: 80 protein-altering or splice-affecting, 31 silent, 14 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 68, Silent 31, Intron 8, Splice Site 6, Nonsense Mutation 4, 3'UTR 2, 3'Flank 2, Frame Shift Ins 2, RNA 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CA | c.1093G>A p.E365K | Missense Mutation (SNP) | VAF 16/142 reads (11%) | hotspot (GDC flag); SIFT deleterious (0.05); PolyPhen benign (0.285); catalogued as rs1064793732, CM126690, COSV55881636, COSV55977337; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.273G>A p.W91* | Nonsense Mutation (SNP) | VAF 58/276 reads (21%) | hotspot (GDC flag); catalogued as rs876660548, CM065495, COSV52673580; ClinVar: pathogenic; called by muse, mutect2, varscan2
- CORO1B | c.184G>A p.V62M | Missense Mutation (SNP) | VAF 56/350 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100396249; called by muse, mutect2, varscan2
- CREM | c.921G>C p.K307N (on ENST00000429130; = p.K262N on NM_181571.3) | Missense Mutation (SNP) | VAF 20/75 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59768589; called by muse, mutect2, varscan2
- FRAS1 | c.8731A>G p.I2911V | Missense Mutation (SNP) | VAF 10/85 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs779649683; called by muse, mutect2, varscan2
- GDF10 | c.1133G>T p.R378L | Missense Mutation (SNP) | VAF 64/407 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1333618871; called by muse, mutect2, varscan2
- GOT1L1 | c.346G>A p.V116I | Missense Mutation (SNP) | VAF 32/230 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.192); catalogued as rs759504357; called by muse, mutect2, varscan2
- IRGQ | c.785C>T p.T262I | Missense Mutation (SNP) | VAF 12/120 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.221); catalogued as rs766863233; called by muse, mutect2
- IRS4 | c.439G>T p.V147L | Missense Mutation (SNP) | VAF 6/106 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.951); catalogued as COSV100929815; called by muse, mutect2
- ITGB5 | c.1810G>A p.E604K | Missense Mutation (SNP) | VAF 132/722 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.014); catalogued as rs574639100, COSV56151565; called by muse, mutect2, varscan2
- LILRB5 | c.1167G>C p.Q389H | Missense Mutation (SNP) | VAF 72/384 reads (19%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs1024050083; called by muse, mutect2, varscan2
- MEF2A | c.992C>T p.P331L (on ENST00000557942 / NM_001319206.2; = p.P325L on NM_005587.4 and 8 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 21/80 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57530835; called by muse, mutect2, varscan2
- NBAS | c.2356C>G p.L786V | Missense Mutation (SNP) | VAF 32/178 reads (18%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.918); catalogued as rs763955825; called by muse, mutect2, varscan2
- P2RX1 | c.8G>A p.R3Q | Missense Mutation (SNP) | VAF 45/200 reads (23%) | SIFT tolerated (0.95); PolyPhen benign (0); catalogued as rs747987720, COSV99844844; called by muse, mutect2, varscan2
- PAMR1 | c.1732C>A p.P578T (on ENST00000619888 / NM_001001991.3; = p.P595T on NM_015430.4) | Missense Mutation (SNP) | VAF 42/371 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53513165; called by muse, mutect2, varscan2
- PCDHA10 | c.47C>A p.S16* | Nonsense Mutation (SNP) | VAF 30/160 reads (19%) | catalogued as COSV100250846, COSV56493138, COSV56555717; called by muse, varscan2
- PCDHB12 | c.2336C>T p.T779I | Missense Mutation (SNP) | VAF 14/95 reads (15%) | SIFT tolerated, low confidence (0.35); PolyPhen benign (0.003); catalogued as rs782239851; called by muse, mutect2, varscan2
- PON2 | c.827C>T p.S276L | Missense Mutation (SNP) | VAF 15/161 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.217); catalogued as rs371244246; called by muse, mutect2, varscan2
- RAG2 | c.1471C>A p.P491T | Missense Mutation (SNP) | VAF 18/375 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57557367; called by muse, mutect2
- RUNX1 | c.710dup p.S238Efs*335 (on ENST00000344691 / NM_001001890.3; = p.S265Efs*335 on NM_001754.5) | Frame Shift Ins (INS) | VAF 66/295 reads (22%) | catalogued as COSV55884823; called by mutect2, pindel, varscan2
- SLC36A1 | c.143+1G>A p.X48_splice | Splice Site (SNP) | VAF 30/150 reads (20%) | catalogued as rs774010579, COSV54652636; called by muse, mutect2, varscan2
- TBX4 | c.1019G>A p.R340Q | Missense Mutation (SNP) | VAF 106/662 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.978); catalogued as rs778365568; called by mutect2, varscan2
- USH2A | c.11275G>A p.A3759T | Missense Mutation (SNP) | VAF 57/332 reads (17%) | SIFT tolerated (0.89); PolyPhen benign (0); catalogued as COSV56343130; called by muse, mutect2, varscan2
- ZBBX | c.148C>T p.R50* | Nonsense Mutation (SNP) | VAF 8/43 reads (19%) | catalogued as rs770966283; called by muse, mutect2, varscan2
- ATXN7L1 | c.355+2T>A p.X119_splice | Splice Site (SNP) | VAF 17/163 reads (10%) | called by muse, mutect2, varscan2
- CDK5RAP2 | c.782G>A p.G261E | Missense Mutation (SNP) | VAF 60/331 reads (18%) | SIFT tolerated (0.78); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- CNNM2 | c.344G>C p.W115S | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT tolerated (0.44); PolyPhen benign (0.019); called by muse, mutect2
- CTRB2 | c.700G>A p.G234S | Missense Mutation (SNP) | VAF 45/265 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.881); called by muse, mutect2, varscan2
- CYP26B1 | c.191A>G p.H64R | Missense Mutation (SNP) | VAF 22/187 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.477); called by muse, mutect2, varscan2
- FBL | c.49G>T p.G17C | Missense Mutation (SNP) | VAF 8/63 reads (13%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.391); called by muse, mutect2, varscan2
- FCGBP | c.4586-1G>A p.X1529_splice | Splice Site (SNP) | VAF 90/1018 reads (9%) | called by muse, varscan2
- GFI1 | c.283C>T p.P95S | Missense Mutation (SNP) | VAF 17/336 reads (5%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.996); called by muse, mutect2
- GLRA4 | c.43T>C p.W15R | Missense Mutation (SNP) | VAF 24/134 reads (18%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- GPCPD1 | c.1837G>C p.D613H | Missense Mutation (SNP) | VAF 19/123 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.887); called by muse, mutect2, varscan2
- GPD2 | c.823A>C p.T275P | Missense Mutation (SNP) | VAF 16/212 reads (8%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.962); called by muse, mutect2
- HCST | c.272G>T p.G91V | Missense Mutation (SNP) | VAF 7/137 reads (5%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.119); called by muse, mutect2
- HNF1B | c.871G>T p.V291F | Missense Mutation (SNP) | VAF 39/410 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.054); called by muse, mutect2, varscan2
- HRH4 | c.572C>T p.A191V | Missense Mutation (SNP) | VAF 13/450 reads (3%) | SIFT tolerated (0.08); PolyPhen benign (0.248); called by muse, mutect2
- IFFO1 | c.1515G>C p.K505N (on ENST00000396840 / NM_001330324.2; = p.K508N on NM_080730.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 28/179 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- IL1RAPL1 | c.1994A>C p.K665T | Missense Mutation (SNP) | VAF 60/337 reads (18%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- ITGA10 | c.640G>C p.V214L | Missense Mutation (SNP) | VAF 39/191 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.649); called by muse, mutect2, varscan2
- KCTD9 | c.954T>A p.S318R | Missense Mutation (SNP) | VAF 7/69 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- LCT | c.3113T>G p.L1038W | Missense Mutation (SNP) | VAF 39/380 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- MTERF2 | c.664A>T p.N222Y | Missense Mutation (SNP) | VAF 32/129 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.34); called by muse, mutect2, varscan2
- MUC1 | c.214A>T p.T72S | Missense Mutation (SNP) | VAF 344/772 reads (45%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.263); called by muse, mutect2, varscan2
- MYO7B | c.850-1G>A p.X284_splice | Splice Site (SNP) | VAF 27/171 reads (16%) | called by muse, mutect2, varscan2
- OLFML2A | c.595G>C p.G199R | Missense Mutation (SNP) | VAF 38/515 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); called by muse, mutect2
- PACS1 | c.274C>A p.P92T | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.959); called by muse, varscan2
- PARP1 | c.1809G>T p.Q603H | Missense Mutation (SNP) | VAF 38/562 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.015); called by muse, mutect2
- PCDHGA3 | c.369T>G p.I123M | Missense Mutation (SNP) | VAF 34/141 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.953); called by muse, mutect2, varscan2
- PLCB3 | c.1731+1G>T p.X577_splice | Splice Site (SNP) | VAF 11/80 reads (14%) | called by muse, mutect2, varscan2
- PLXNA1 | c.5030A>T p.E1677V | Missense Mutation (SNP) | VAF 39/150 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- POM121L12 | c.647C>A p.A216D | Missense Mutation (SNP) | VAF 34/396 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- PPBP | c.245T>C p.V82A | Missense Mutation (SNP) | VAF 19/232 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.906); called by muse, mutect2
- PRKG1 | c.983dup p.C328Wfs*5 | Frame Shift Ins (INS) | VAF 9/80 reads (11%) | called by mutect2, pindel, varscan2
- PTPRR | c.277T>A p.S93T | Missense Mutation (SNP) | VAF 72/345 reads (21%) | SIFT tolerated, low confidence (0.08); PolyPhen probably damaging (0.952); called by muse, mutect2, varscan2
- RAB3IP | c.298A>T p.S100C (on ENST00000550536 / NM_175623.4; = p.S84C on NM_022456.5) | Missense Mutation (SNP) | VAF 15/74 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- RILP | c.418G>T p.E140* | Nonsense Mutation (SNP) | VAF 9/31 reads (29%) | called by muse, varscan2
- RXFP2 | c.392C>G p.S131C | Missense Mutation (SNP) | VAF 43/194 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.469); called by muse, mutect2, varscan2
- SCN2A | c.5261T>A p.F1754Y | Missense Mutation (SNP) | VAF 39/397 reads (10%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.916); called by muse, mutect2, varscan2
- SGO2 | c.2011G>C p.A671P | Missense Mutation (SNP) | VAF 11/49 reads (22%) | SIFT tolerated (0.23); PolyPhen benign (0.054); called by muse, mutect2, varscan2
- SLC30A2 | c.668A>G p.D223G | Missense Mutation (SNP) | VAF 26/98 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.877); called by muse, mutect2, varscan2
- SLC44A4 | c.1582+1G>T p.X528_splice | Splice Site (SNP) | VAF 12/324 reads (4%) | called by muse, mutect2
- SLC6A17 | c.1858C>T p.L620F | Missense Mutation (SNP) | VAF 50/200 reads (25%) | SIFT tolerated (0.1); PolyPhen benign (0.231); called by muse, mutect2, varscan2
- SLC7A14 | c.711T>A p.N237K | Missense Mutation (SNP) | VAF 66/442 reads (15%) | SIFT tolerated (0.16); PolyPhen benign (0); called by muse, mutect2, varscan2
- SORCS3 | c.1588C>T p.P530S | Missense Mutation (SNP) | VAF 24/127 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SPATA31D1 | c.4186T>C p.F1396L | Missense Mutation (SNP) | VAF 16/286 reads (6%) | SIFT tolerated (0.59); PolyPhen benign (0.028); called by muse, mutect2
- STPG1 | c.70G>A p.G24S (on ENST00000337248 / NM_001199013.2; = p.K16= on NM_178122.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/190 reads (4%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); called by muse, mutect2
- SYNE1 | c.5487G>T p.K1829N (on ENST00000367255 / NM_182961.4; = p.K1836N on NM_033071.3) | Missense Mutation (SNP) | VAF 24/211 reads (11%) | SIFT tolerated (0.13); PolyPhen benign (0); called by muse, mutect2, varscan2
- TBCE | c.752T>G p.V251G (on ENST00000366601; = p.V314G on NM_003193.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 83/611 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.786); called by muse, mutect2, varscan2
- TIE1 | c.1364T>A p.L455H | Missense Mutation (SNP) | VAF 32/194 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TIMP2 | c.561G>T p.Q187H | Missense Mutation (SNP) | VAF 141/665 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TMEM143 | c.992G>A p.R331H | Missense Mutation (SNP) | VAF 11/168 reads (7%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.971); called by muse, mutect2
- TNFAIP3 | c.651T>G p.S217R | Missense Mutation (SNP) | VAF 8/79 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- TRAF1 | c.814A>G p.K272E | Missense Mutation (SNP) | VAF 48/263 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.224); called by muse, mutect2, varscan2
- TRIM64C | c.263C>T p.S88L | Missense Mutation (SNP) | VAF 95/638 reads (15%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.706); called by muse, mutect2, varscan2
- TSR3 | c.304G>C p.G102R | Missense Mutation (SNP) | VAF 14/72 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- VPS72 | c.589A>G p.K197E | Missense Mutation (SNP) | VAF 69/331 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); called by muse, varscan2
- ZBTB24 | c.1082C>G p.T361S | Missense Mutation (SNP) | VAF 52/277 reads (19%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- ZGRF1 | c.824C>G p.T275R | Missense Mutation (SNP) | VAF 10/204 reads (5%) | SIFT tolerated (0.08); PolyPhen benign (0.325); called by muse, mutect2
- ANKRD11 | c.3744C>T p.A1248= | Silent (SNP) | VAF 43/184 reads (23%) | catalogued as rs780584993; called by muse, mutect2, varscan2
- BMX | c.384G>A p.G128= | Silent (SNP) | VAF 29/190 reads (15%) | called by muse, varscan2
- CAMK2B | c.936G>A p.R312= | Silent (SNP) | VAF 15/168 reads (9%) | called by muse, mutect2
- CEL | c.1791G>A p.P597= (on ENST00000673714; = p.P594= on NM_001807.6) | Silent (SNP) | VAF 25/104 reads (24%) | catalogued as rs774455699; called by muse, varscan2
- DPP6 | c.2010C>A p.T670= (on ENST00000377770 / NM_001364500.2; = p.T608= on NM_001936.5) | Silent (SNP) | VAF 21/106 reads (20%) | called by muse, mutect2, varscan2
- DSTYK | c.39C>G p.V13= | Silent (SNP) | VAF 29/98 reads (30%) | catalogued as rs1239672273; called by muse, mutect2, varscan2
- EIF3L | c.1617T>C p.Y539= | Silent (SNP) | VAF 14/150 reads (9%) | catalogued as rs375291218; called by muse, mutect2
- GPR88 | c.1032C>G p.R344= | Silent (SNP) | VAF 24/71 reads (34%) | called by muse, mutect2, varscan2
- GSX2 | c.600C>T p.P200= | Silent (SNP) | VAF 37/228 reads (16%) | called by muse, mutect2, varscan2
- KLB | c.600G>A p.L200= | Silent (SNP) | VAF 25/251 reads (10%) | called by muse, mutect2, varscan2
- KMT2D | c.7104C>T p.I2368= | Silent (SNP) | VAF 41/234 reads (18%) | called by muse, mutect2, varscan2
- LRCH2 | c.1071A>T p.R357= | Silent (SNP) | VAF 5/59 reads (8%) | called by muse, mutect2
- LRRC43 | c.1056C>T p.G352= | Silent (SNP) | VAF 19/119 reads (16%) | catalogued as rs779792928, COSV60290130, COSV60293387; called by muse, mutect2, varscan2
- PCDHA11 | c.2229G>A p.A743= | Silent (SNP) | VAF 42/222 reads (19%) | catalogued as COSV56479720; called by muse, mutect2, varscan2
- PCSK1N | c.732C>G p.R244= | Silent (SNP) | VAF 23/89 reads (26%) | called by muse, mutect2, varscan2
- PKHD1 | c.3753C>A p.T1251= | Silent (SNP) | VAF 100/498 reads (20%) | catalogued as COSV100582460; called by muse, mutect2
- RAD51D | c.255C>T p.G85= | Silent (SNP) | VAF 61/471 reads (13%) | catalogued as rs750714062; ClinVar: likely benign; called by muse, mutect2, varscan2
- RCN1 | c.66G>A p.L22= | Silent (SNP) | VAF 5/42 reads (12%) | catalogued as rs746555362; called by mutect2, varscan2
- RRAGB | c.786T>C p.D262= (on ENST00000262850 / NM_016656.4; = p.D234= on NM_006064.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 50/231 reads (22%) | catalogued as rs1214939527; called by muse, mutect2, varscan2
- SLC12A7 | c.831G>T p.A277= | Silent (SNP) | VAF 53/373 reads (14%) | catalogued as COSV53760100; called by muse, mutect2, varscan2
- SLC35C2 | c.582C>G p.L194= | Silent (SNP) | VAF 71/375 reads (19%) | catalogued as COSV99709022; called by muse, mutect2, varscan2
- SORBS1 | c.45C>A p.G15= | Silent (SNP) | VAF 18/228 reads (8%) | called by muse, mutect2
- SORCS3 | c.1587T>C p.A529= | Silent (SNP) | VAF 24/128 reads (19%) | catalogued as rs200408993; called by muse, mutect2, varscan2
- SPTBN4 | c.4275G>A p.K1425= | Silent (SNP) | VAF 80/530 reads (15%) | called by muse, mutect2, varscan2
- SREBF2 | c.3022C>T p.L1008= | Silent (SNP) | VAF 63/966 reads (7%) | catalogued as rs367924676, COSV63331401; called by muse, mutect2
- STAB2 | c.1335C>T p.I445= | Silent (SNP) | VAF 7/79 reads (9%) | catalogued as rs760437478, COSV66340908; called by muse, mutect2, varscan2
- TIE1 | c.1365C>A p.L455= | Silent (SNP) | VAF 32/195 reads (16%) | called by muse, mutect2, varscan2
- TNR | c.1095G>A p.G365= | Silent (SNP) | VAF 108/713 reads (15%) | catalogued as rs376191863; called by muse, mutect2, varscan2
- TNS1 | c.3687T>A p.T1229= | Silent (SNP) | VAF 42/686 reads (6%) | called by muse, mutect2
- TTC7A | c.1047C>A p.L349= | Silent (SNP) | VAF 24/221 reads (11%) | catalogued as rs1376842670; called by muse, mutect2, varscan2
- WFS1 | c.1512G>A p.P504= | Silent (SNP) | VAF 81/706 reads (11%) | catalogued as rs201684148; called by muse, mutect2, varscan2
- AKR1B15 | c.150+719C>T | Intron (SNP) | VAF 35/157 reads (22%) | catalogued as rs777675642; called by muse, mutect2, varscan2
- CITED2 | c.*34C>T | 3'UTR (SNP) | VAF 13/161 reads (8%) | catalogued as rs1394886234; called by muse, mutect2
- CLCN5 | c.17-33345C>G | Intron (SNP) | VAF 47/248 reads (19%) | catalogued as rs1432884260, COSV101067374; called by muse, mutect2, varscan2
- CRYBG3 | c.*37C>T | 3'UTR (SNP) | VAF 8/40 reads (20%) | called by muse, mutect2
- DHRS9 | c.-9G>A | 5'UTR (SNP) | VAF 41/234 reads (18%) | catalogued as rs753203203; called by muse, mutect2, varscan2
- NRG1 | c.502+30990G>A | Intron (SNP) | VAF 68/358 reads (19%) | catalogued as rs909625047; called by muse, mutect2, varscan2
- OR2W5 | n.1130C>A | RNA (SNP) | VAF 23/428 reads (5%) | called by muse, mutect2
- PFKM | c.1501-26C>G | Intron (SNP) | VAF 141/682 reads (21%) | called by muse, mutect2, varscan2
- RN7SL484P | chr15:99792226 G>A | 3'Flank (SNP) | VAF 37/310 reads (12%) | catalogued as rs764279245; called by muse, mutect2, varscan2
- SLC2A6 | c.92+47C>T | Intron (SNP) | VAF 11/106 reads (10%) | catalogued as rs782292014; called by muse, mutect2, varscan2
- SSH1 | c.111-2749G>T | Intron (SNP) | VAF 9/66 reads (14%) | called by muse, mutect2, varscan2
- SSH1 | c.111-2750G>T | Intron (SNP) | VAF 9/65 reads (14%) | called by muse, mutect2, varscan2
- TBX2 | c.1051+167C>T | Intron (SNP) | VAF 107/515 reads (21%) | catalogued as COSV53598152; called by muse, mutect2, varscan2
- TRIM73 | chr7:75415685 G>A | 3'Flank (SNP) | VAF 23/224 reads (10%) | called by muse, mutect2, varscan2
